Somatic mutation profile of tumor specimen ALCH-B1UH-TTP1-A (aliquot ALCH-B1UH-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1UH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,364 days).
Specimen ALCH-B1UH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 987ef9fc-d80c-452f-842f-965372589acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UH-NB1-A (Blood Derived Normal), aliquot ALCH-B1UH-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db7290b-535d-4ffe-a8ba-2e4ebd77be69

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.7039A>G p.I2347V | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs751090175; called by muse, mutect2, varscan2
- BBS12 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1374978369; called by muse, mutect2, varscan2
- IGHV3-38 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); catalogued as rs762002371; called by muse, mutect2, varscan2
- NLGN4Y | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777972303; called by muse, mutect2, varscan2
- USP36 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61750579; called by muse, mutect2
- ARHGAP27 | c.611T>A p.V204D | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDKL3 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2
- KIAA1549L | c.2113A>G p.T705A (on ENST00000321505; = p.T1002A on NM_012194.3) | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); called by muse, mutect2
- MARCHF7 | c.1549A>G p.K517E | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RCVRN | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FRAS1 | c.11691G>A p.A3897= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs763273156, COSV53590210, COSV99351236; called by muse, mutect2, varscan2
- PPFIA3 | c.627G>A p.L209= | Silent (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- FGFR4 | c.1058-176G>A | Intron (SNP) | VAF 24/294 reads (8%) | catalogued as rs576367362; called by muse, mutect2
- G6PD | c.267+28del | Intron (DEL) | VAF 24/118 reads (20%) | called by mutect2, pindel, varscan2
- RAPSN | c.1166+19del | Intron (DEL) | VAF 4/22 reads (18%) | catalogued as rs760797252; called by pindel, varscan2
